Somatic mutation profile of tumor specimen TARGET-20-PASHYZ-09A (aliquot TARGET-20-PASHYZ-09A-02D) from TARGET case TARGET-20-PASHYZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,695 days).
Specimen TARGET-20-PASHYZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec0a71c9-ee24-4e6e-8e7d-f5b7b7734afb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHYZ-14A (Bone Marrow Normal), aliquot TARGET-20-PASHYZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58e3225e-19ae-4628-98cc-2ab0c33ec026

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.12545G>T p.G4182V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV71674346; called by muse, mutect2, varscan2
- ASXL2 | c.1571_1572insCC p.P525Rfs*14 | Frame Shift Ins (INS) | VAF 30/191 reads (16%) | called by mutect2, pindel, varscan2
- KIT | c.2460_2465delinsGACTTT p.D820_N822delinsETF | Missense Mutation (ONP) | VAF 26/108 reads (24%) | called by mutect2*, pindel
